TCGA case TCGA-AR-A24M — Breast Invasive Carcinoma (TCGA-BRCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast; Tissue source site: Mayo. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/aa30ac3d-4216-45dd-a314-1ae192fafcb2

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 38 years; Vital status: Alive.

Diagnoses (1)
1. Infiltrating duct and lobular carcinoma: ICD-O-3 morphology code: 8522/3; ICD-10 code: C50.9; Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Breast, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 38.7 years (14,119 days); Year of diagnosis: 2005; Method of diagnosis: Core Biopsy; AJCC staging edition: 6th; AJCC pathologic T: T2; AJCC pathologic N: N2; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Breast, Left Upper Outer.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 4; Lymph nodes tested: 28.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Tamoxifen; Treatment intent type: Adjuvant; Days to treatment start: 171 days; Days to treatment end: 597 days (1.6 years); Prescribed dose: 20; Prescribed dose units: mg/day; Route of administration: Oral.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 172 days; Days to treatment end: 221 days; Treatment dose: 6,040 cGy; Course number: 1; Number of fractions: 33; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Letrozole; Treatment intent type: Adjuvant; Days to treatment start: 597 days (1.6 years); Treatment outcome: Treatment Ongoing; Prescribed dose: 2.5; Prescribed dose units: mg/day; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide; Treatment intent type: Adjuvant; Number of cycles: 4.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Doxorubicin; Treatment intent type: Adjuvant; Number of cycles: 4.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Number of cycles: 4.
   Treatment given: Treatment type: Surgery, NOS; Treatment intent type: First-Line Therapy; Initial disease status: Initial Diagnosis; Margin status: Uninvolved; Treatment anatomic sites: Breast.

Follow-up (3 entries)
- Days to follow up: 2,947 days (8.1 years); Disease response: Tumor Free.
- Days to follow up: 3,660 days (10.0 years); Disease response: Tumor Free.
- Follow-up contact recording only the day: day 1,991.

Molecular and laboratory tests
- ERBB2 (IHC): Negative; Staining intensity value: 1+.
- ESR1 (IHC): Positive; Test value range: 10-19%.
- PGR (IHC): Positive; Test value range: 10-19%.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Menopause status: Premenopausal.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-AR-A24M-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 400 mg.
  Slide TCGA-AR-A24M-01A-01-TSA: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 75; Percent normal cells: 2; Percent necrosis: 0; Percent stromal cells: 23; Percent lymphocyte infiltration: 4; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 1.
- Sample TCGA-AR-A24M-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-AR-A24M-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Lymph nodes examined: Yes; Axillary staging method: Sentinel lymph node biopsy plus axillary dissection; First surgical procedure other: Wide local excision; Histologic diagnosis: Mixed Histology (please specify); Histologic diagnosis other: Mixed invasive ductal and invasive lobular; Menopause status: Pre (<6 months since LMP AND no prior bilateral ovariectomy AND not on estrogen replacement); Her2 IHC score: 1+; Method initial path diagnosis: Core needle biopsy; Prospective collection: No; Retrospective collection: Yes.
- Anatomic neoplasm subdivisions: Anatomic organ subdivision: Left Upper Outer Quadrant.
- Follow-up form 1: New tumor event diagnosis indicator: No.
- Follow-up form 2: Lost to follow-up: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Drug treatment 1: Regimen number: 1; Pharmaceutical therapy drug name: Cytoxan.
- Drug treatment 2: Regimen number: 2.
- Drug treatment 2, Route of administrations: Route of administration: PO.
- Drug treatment 5: Regimen number: 3.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 3,660 days; disease-specific survival: no event (censored), 3,660 days; disease-free interval: no event (censored), 3,660 days; progression-free interval: no event (censored), 3,660 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-AR-A24M-01A-11D-A166-01): tumor purity 0.69, ploidy 2.16, whole-genome doublings 0.
